Surgical pathology report (de-identified scan), TCGA case TCGA-06-2561, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2561-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-2561

CLINICAL HISTORY

Recurrent brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain tumor, biopsy
B: Brain, right temporal tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

and B. Brain, right temporal tumor, excision: Glioblastoma (WHO Grade IV)
(see comment).

COMMENT

Sections show a pleomorphic high-grade astrocytoma with gemistocytic and some giant cell features. Occasional mitotic figures, microvascular proliferation and pseudopalisading necrosis are present. Results of immunohistochemical and molecular studies will be reported in procedure addenda.

PROCEDURES/ADDENDA

Immunohistology

Date Ordered: Date Reported:

Interpretation

The results are compatible with glioblastoma.

Results-Comments

The tumor nuclei show diffuse weak to strong p53 immunoreactivity.
The Ki-67 labeling index is approximately 20%.

[page 2 of 3]
Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[page 3 of 3]
INTRA-OPERATIVE CONSULTATION

A. Brain tumor, biopsy: Recurrent/residual high-grade astrocytoma. Frozen section and smears performed on part A. at [REDACTED] and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A. Received labeled with the patient's name and MRN are 3 pieces of soft tan tissue, approximately 0.8 x 0.8 x 0.4 cm in aggregate. Small samples are used for frozen sections and smears. The frozen residual is submitted in A1 and the unfrozen tissue is submitted A2.

B. Brain, right temporal tumor, biopsy: CONTAINER LABEL: right temporal brain tumor.

FIXATIVE: Formalin. NO. PIECES: several. SIZE/VOL: aggregate 2.0x2.0x0.9 cm.; 1.25 grams CASSETTES: 1,2 NS.

ICD-9(s):
191.2 191.2

Histo Data

Part A: Brain tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
MGMT-curls x 1	2	[REDACTED]	
EGFR vIII-curls x 1	(none)	[REDACTED]	

Part B: Brain, right temporal tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
31-DA x 1	2	[REDACTED]	
p53DO7 x 1	2	[REDACTED]	

Source: NCI Genomic Data Commons file 95e250ed-e486-4230-9a23-65d1f8e13ff5 (TCGA-06-2561.15CB8BF0-7C77-4752-87B5-B67BB2776B76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).